Somatic mutation profile of tumor specimen TCGA-VQ-AA64-01A (aliquot TCGA-VQ-AA64-01A-11D-A410-08) from TCGA case TCGA-VQ-AA64, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 68.7 years (25,109 days).
Specimen TCGA-VQ-AA64-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99fc5c61-64b4-4c15-96ea-44dc2d86cdaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-AA64-10A (Blood Derived Normal), aliquot TCGA-VQ-AA64-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7cde846-f496-4896-95cc-08be7c8ef4c5

The open-access MAF lists 300 somatic variants for this specimen: 222 protein-altering or splice-affecting, 68 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 177, Silent 68, Frame Shift Del 17, Nonsense Mutation 14, In Frame Del 9, Splice Site 4, Intron 4, RNA 4, Frame Shift Ins 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.6655T>G p.F2219V (on ENST00000272895 / NM_173076.3; = p.F1901V on NM_015657.3) | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99791074; called by muse, mutect2, varscan2
- ABL2 | c.1167G>A p.M389I (on ENST00000502732 / NM_007314.4; = p.M374I on NM_005158.5) | Missense Mutation (SNP) | VAF 58/112 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as COSV100772886; called by muse, mutect2, varscan2
- ADAMTS16 | c.1709G>A p.R570Q | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs541447897, COSV56989256; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1159C>G p.R387G | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs763308439, COSV99647624; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRA3 | c.629G>C p.R210P | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as COSV99293557; called by muse, mutect2, varscan2
- ADGRF1 | c.592G>T p.V198F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99347471; called by muse, mutect2, varscan2
- ADIPOQ | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100292223; called by muse, mutect2, varscan2
- AJAP1 | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV100981923; called by muse, mutect2
- AKR1B15 | c.167T>G p.V56G | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV101423395; called by muse, mutect2, varscan2
- ALOX15 | c.1310C>A p.T437N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99541579; called by muse, mutect2, varscan2
- AMY2B | c.114T>A p.D38E | Missense Mutation (SNP) | VAF 60/683 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100796410; called by muse, mutect2
- ANO5 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749374398, COSV100201748, COSV61086066; called by muse, mutect2, varscan2
- APBA2 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.536); catalogued as rs771125386, COSV68796189; called by muse, mutect2, varscan2
- APBA2 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.09); catalogued as rs1416887852, COSV68792476; called by muse, mutect2, varscan2
- ARHGEF26 | c.2456A>G p.Y819C | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs758556543, COSV100726656; called by muse, mutect2, varscan2
- ARSI | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs149628658; called by muse, mutect2, varscan2
- ASPSCR1 | c.318C>G p.D106E | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV100144957; called by muse, mutect2, varscan2
- ATP10D | c.2894T>G p.L965R | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99905912; called by muse, mutect2, varscan2
- ATP8A1 | c.1983T>A p.D661E | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100046783; called by muse, mutect2, varscan2
- B3GNTL1 | c.295C>G p.Q99E | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as rs1486310919, COSV100302132; called by muse, mutect2, varscan2
- BCL11A | c.2351A>C p.H784P (on ENST00000335712 / NM_001365609.1; = p.H818P on NM_022893.4) | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100186118; called by muse, mutect2, varscan2
- C5AR2 | c.477G>T p.W159C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99953838; called by muse, mutect2, varscan2
- CABLES2 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751037345, COSV99653235; called by muse, mutect2, varscan2
- CCDC40 | c.3419G>A p.G1140E | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as COSV100163385, COSV100163633; called by muse, mutect2
- CCDC6 | c.957T>A p.C319* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV99569672; called by muse, mutect2, varscan2
- CCN3 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV99423194; called by muse, mutect2
- CDH16 | c.259G>T p.E87* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100234017, COSV100234317; called by muse, mutect2, varscan2
- CDH9 | c.2141A>G p.D714G | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.788); catalogued as COSV50557648; called by muse, mutect2, varscan2
- CDKN2A | c.245T>A p.V82E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV58688645, COSV58696370, COSV58710340; called by muse, mutect2, varscan2
- CEACAM3 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1160309705, COSV55760740, COSV99705050; called by muse, mutect2, varscan2
- CHST1 | c.1086C>A p.F362L | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs777806565, COSV100346389, COSV57323599; called by muse, mutect2, varscan2
- CMYA5 | c.6195C>G p.I2065M | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV101484218; called by muse, mutect2, varscan2
- CNOT1 | c.1123C>T p.H375Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100409732; called by muse, mutect2, varscan2
- COQ10B | c.140C>G p.T47S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99827418; called by muse, mutect2, varscan2
- CRIM1 | c.979G>C p.E327Q | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as COSV99753939; called by muse, mutect2, varscan2
- CRLF3 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 15/80 reads (19%) | catalogued as COSV100158466; called by muse, mutect2, varscan2
- CRMP1 | c.803G>A p.R268K | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.09); catalogued as COSV100272145; called by muse, mutect2, varscan2
- CUX2 | c.881G>C p.C294S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV99920242; called by muse, mutect2, varscan2
- DGUOK | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99903596; called by muse, mutect2, varscan2
- DIP2C | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99792895; called by muse, mutect2, varscan2
- DNAH1 | c.3227C>A p.A1076D | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV101326494; called by muse, mutect2, varscan2
- DNAH11 | c.3804T>A p.Y1268* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100179921, COSV60981565; called by muse, mutect2, varscan2
- DNAH17 | c.5747T>G p.V1916G | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101102920; called by muse, mutect2, varscan2
- DNAH2 | c.3973C>T p.R1325W | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.697); catalogued as rs199664791, COSV66717280; called by muse, mutect2, varscan2
- DOCK2 | c.1717C>A p.H573N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs769013637, COSV99914057; called by muse, mutect2, varscan2
- DOCK7 | c.3787C>G p.H1263D (on ENST00000635253 / NM_001367561.1; = p.H1232D on NM_033407.3) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.039); catalogued as COSV99225302; called by muse, mutect2, varscan2
- DST | c.9337G>C p.E3113Q | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.181); catalogued as COSV99758341; called by muse, mutect2, varscan2
- DST | c.6283G>T p.E2095* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as COSV99758342; called by muse, varscan2
- DST | c.6223G>T p.E2075* | Nonsense Mutation (SNP) | VAF 24/103 reads (23%) | catalogued as COSV55001881, COSV99758344; called by muse, varscan2
- EEF1AKMT4-ECE2 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs754312859, COSV62567475; called by muse, mutect2, varscan2
- EIF2D | c.1552T>C p.Y518H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV99662934; called by muse, mutect2, varscan2
- ELAC1 | c.161G>C p.R54T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs778267003, COSV99494986; called by muse, mutect2, varscan2
- ELAVL4 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100836822; called by muse, varscan2
- EML1 | c.1732G>T p.V578F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs376629514, COSV99214370, COSV99215314; called by muse, mutect2, varscan2
- ENPEP | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as rs143343563, COSV54448047; called by muse, mutect2, varscan2
- FOXK1 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 16/114 reads (14%) | catalogued as rs1397177767, COSV61065914; called by muse, mutect2, varscan2
- FREM1 | c.1912G>T p.D638Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101085011; called by muse, mutect2, varscan2
- FRY | c.2651T>G p.L884R | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100969622; called by muse, mutect2
- GABBR1 | c.2086G>C p.E696Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.795); catalogued as COSV100589899; called by muse, mutect2, varscan2
- GABBR2 | c.2305G>C p.E769Q | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV99410843; called by muse, mutect2
- GJB1 | c.9G>C p.W3C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM004044, COSV100661288; called by muse, mutect2, varscan2
- GML | c.359G>T p.R120M | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV55277820, COSV55278836; called by muse, mutect2, varscan2
- GNRH1 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV99373654; called by muse, mutect2, varscan2
- GOLGA6A | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs1177352375, COSV51804349; called by mutect2, varscan2
- GPAT2 | c.1189G>T p.G397C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV100853331; called by muse, mutect2, varscan2
- GRK4 | c.664A>G p.R222G (on ENST00000398052 / NM_182982.3; = p.R190G on NM_005307.3) | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1451518141, COSV100584182, COSV61668627; called by muse, mutect2, varscan2
- HEXIM1 | c.576G>C p.E192D | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100203538; called by muse, mutect2, varscan2
- HIKESHI | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as rs1486806929, COSV99563555; called by muse, mutect2, varscan2
- HMOX1 | c.53A>C p.K18T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99330780; called by muse, mutect2, varscan2
- IGSF10 | c.446T>C p.F149S | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99184751; called by muse, mutect2, varscan2
- IL11RA | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754675321, COSV99426547; called by muse, mutect2, varscan2
- IL12RB2 | c.779G>A p.R260Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as rs771299847, COSV52021440; called by muse, mutect2, varscan2
- INTS6L | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100878197; called by muse, mutect2, varscan2
- IPCEF1 | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99500108; called by muse, mutect2, varscan2
- IRX2 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as rs1259588092, COSV100121825, COSV57409564; called by muse, mutect2, varscan2
- IZUMO2 | c.551G>T p.R184M | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV99518338; called by muse, mutect2, varscan2
- KCNA6 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99768798; called by muse, mutect2, varscan2
- KCNC2 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs749901519, COSV100129436; called by muse, mutect2, varscan2
- KCNJ1 | c.1107G>A p.M369I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs553487085, COSV60662591; called by muse, mutect2, varscan2
- KCNQ5 | c.953C>A p.T318N | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100572564; called by muse, mutect2, varscan2
- KCNV1 | c.634T>G p.F212V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV99819270; called by muse, mutect2, varscan2
- KDM2A | c.2243A>G p.H748R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.61); catalogued as COSV100445739; called by muse, mutect2, varscan2
- KIF20B | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV99590421; called by muse, mutect2, varscan2
- KLHL40 | c.1443C>A p.C481* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99825667; called by muse, mutect2, varscan2
- KRT35 | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55842865, COSV99877850; called by muse, mutect2, varscan2
- LCE2D | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); catalogued as COSV100909560, COSV64228826; called by muse, mutect2, varscan2
- LDLRAP1 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs367810885; called by muse, mutect2, varscan2
- LILRA4 | c.598A>T p.N200Y | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99393262; called by muse, mutect2, varscan2
- LILRA6 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1555893090, COSV99558104; called by muse, mutect2, varscan2
- LILRB3 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV54439112; called by muse, mutect2
- LRP12 | c.1264C>G p.R422G | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.982); catalogued as COSV99408078; called by muse, mutect2, varscan2
- LYST | c.8084C>G p.S2695C | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV101089966; called by muse, mutect2, varscan2
- MAS1 | c.23C>A p.S8* | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as COSV53120772, COSV53122090; called by muse, mutect2, varscan2
- MCTP1 | c.2318T>C p.L773P | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56503761; called by muse, mutect2, varscan2
- MCTP1 | c.949G>T p.V317F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs769258112, COSV100386363, COSV100387721; called by muse, mutect2, varscan2
- MFSD8 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.253); catalogued as rs1299242517, COSV99614561; called by muse, mutect2, varscan2
- MID1IP1 | c.303C>G p.I101M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.838); catalogued as rs1410393675, COSV100423768; called by muse, mutect2, varscan2
- MMEL1 | c.1646A>T p.Q549L | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV99984162; called by muse, mutect2, varscan2
- MUC16 | c.39128T>C p.L13043P | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101200552; called by muse, mutect2, varscan2
- MYT1L | c.1800C>A p.D600E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs1489513716, COSV101221054; called by muse, mutect2
- NCKAP5 | c.2349G>C p.Q783H | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV100493502; called by muse, mutect2, varscan2
- NDUFAF7 | c.995C>A p.T332K | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99135676; called by muse, mutect2, varscan2
- NFE2L2 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as COSV101229409; called by muse, mutect2, varscan2
- NIPBL | c.2993G>C p.G998A | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.572); catalogued as COSV99241736; called by muse, mutect2, varscan2
- NLRP14 | c.2227G>T p.D743Y | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1444868369, COSV100205237; called by muse, mutect2, varscan2
- NOL4 | c.773-2A>C p.X258_splice | Splice Site (SNP) | VAF 21/47 reads (45%) | catalogued as COSV99307664; called by muse, mutect2, varscan2
- NUMA1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100706402; called by muse, mutect2, varscan2
- OCA2 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as rs371349719; called by muse, mutect2, varscan2
- OR10K2 | c.636G>T p.L212F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.039); catalogued as COSV100149579; called by muse, mutect2, varscan2
- OR2L13 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs948032044, COSV63551913; called by muse, mutect2, varscan2
- OR2M3 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV101513485, COSV71758934; called by muse, mutect2, varscan2
- OR5L1 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs745385243, COSV61733573, COSV61734273, COSV61735834; called by muse, mutect2, varscan2
- OSBP2 | c.1562T>A p.L521H | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100213461; called by muse, mutect2, varscan2
- PALB2 | c.2578G>T p.E860* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV55166130, COSV99848784; called by muse, mutect2, varscan2
- PAN2 | c.31G>C p.A11P | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.441); catalogued as rs1403872784, COSV99228393; called by muse, mutect2, varscan2
- PELO | c.146_149del p.T49Sfs*102 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs768283647; called by pindel, varscan2
- PGD | c.924G>T p.Q308H | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99581554; called by muse, mutect2
- PHF23 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); catalogued as COSV99138646; called by muse, mutect2
- PLD2 | c.1626C>A p.D542E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54003270, COSV99562548; called by muse, mutect2, varscan2
- PLD3 | c.1020G>T p.R340S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); catalogued as rs1269527072, COSV99396879; called by muse, mutect2, varscan2
- PLEKHA4 | c.916G>T p.G306W | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1158499989, COSV99612877; called by muse, mutect2, varscan2
- PLIN4 | c.2975G>T p.S992I (on ENST00000301286; = p.S1007I on NM_001367868.2) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV100013714; called by muse, mutect2, varscan2
- PLXNA1 | c.1982G>A p.C661Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99303682; called by muse, mutect2
- POSTN | c.950G>C p.G317A | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV101123421; called by muse, mutect2, varscan2
- PRG4 | c.2825C>G p.A942G | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as rs1332938342, COSV100798270; called by muse, mutect2, varscan2
- PTPRO | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV55513509; called by muse, mutect2, varscan2
- QSOX2 | c.414C>G p.F138L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.121); catalogued as COSV100699819; called by muse, mutect2, varscan2
- RAPGEF4 | c.2084T>C p.V695A | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV99911147; called by muse, mutect2, varscan2
- RASA2 | c.1012G>C p.D338H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV99656528; called by muse, mutect2, varscan2
- RBM4B | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV100026488; called by muse, mutect2, varscan2
- RNF44 | c.1219G>T p.V407F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99221953; called by muse, varscan2
- RP1L1 | c.2193C>A p.D731E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV101222965; called by muse, mutect2, varscan2
- RUSC2 | c.172G>C p.D58H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100770801; called by muse, mutect2, varscan2
- RYR2 | c.5189C>T p.T1730M | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs745569662, COSV63665961, COSV63668687; called by muse, mutect2, varscan2
- SCAP | c.811C>A p.L271M | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV99653056; called by muse, mutect2, varscan2
- SCN10A | c.5483A>C p.K1828T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs561114332, COSV71860342, COSV71862308; called by muse, mutect2, varscan2
- SCN8A | c.4378A>T p.I1460F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV61981494; called by muse, mutect2, varscan2
- SETDB2 | c.1307G>T p.C436F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.335); catalogued as rs1342831193, COSV99320887; called by muse, mutect2, varscan2
- SFSWAP | c.1165G>A p.V389M | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as rs780510999, COSV99906259; called by muse, mutect2, varscan2
- SLC22A25 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1022750974, COSV100123748; called by muse, mutect2, varscan2
- SLC26A11 | c.552C>A p.F184L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV100755423; called by muse, mutect2, varscan2
- SLC30A8 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs141202988, COSV69969422; called by muse, mutect2, varscan2
- SLC44A5 | c.52+2T>C p.X18_splice | Splice Site (SNP) | VAF 39/81 reads (48%) | catalogued as COSV100902280; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2146G>A p.D716N (on ENST00000540229 / NM_001371097.1; = p.D655N on NM_001009562.4) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.354); catalogued as rs777796391, COSV67439734, COSV67445996; called by muse, mutect2, varscan2
- SLITRK5 | c.1178G>T p.C393F | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100281266, COSV61526234; called by muse, mutect2, varscan2
- SMAD9 | c.1189T>A p.S397T (on ENST00000379826 / NM_001127217.3; = p.S360T on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV100614881; called by muse, mutect2, varscan2
- SMC1B | c.1829A>T p.Q610L | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.033); catalogued as COSV100663391; called by muse, mutect2, varscan2
- SOS1 | c.1071G>C p.L357F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as COSV101217135; called by muse, mutect2, varscan2
- SOX13 | c.112del p.Q38Rfs*71 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as COSV65827178; called by mutect2, pindel
- SPIRE1 | c.806G>T p.W269L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100563868; called by muse, mutect2, varscan2
- TAOK3 | c.1135G>T p.V379F | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV101183642; called by muse, mutect2, varscan2
- TCP11L1 | c.1204C>G p.L402V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV100178275; called by muse, mutect2, varscan2
- TDRD3 | c.1312C>G p.Q438E | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs1324987519, COSV99540894; called by muse, mutect2
- TGFBRAP1 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 54/201 reads (27%) | catalogued as COSV99305314; called by muse, mutect2
- TIAM1 | c.3453A>C p.K1151N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99737418; called by muse, mutect2, varscan2
- TIGAR | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99463841; called by muse, mutect2, varscan2
- TIMMDC1 | c.155A>G p.E52G | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.42); catalogued as COSV99809731; called by muse, mutect2, varscan2
- TLE4 | c.239A>T p.E80V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99512673; called by muse, mutect2, varscan2
- TMPRSS15 | c.2302A>T p.N768Y | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53039338, COSV99518590; called by muse, mutect2, varscan2
- TOGARAM1 | c.4049A>T p.E1350V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100818181; called by muse, mutect2, varscan2
- TRAF5 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99807504; called by muse, mutect2, varscan2
- TRIB1 | c.1112_1114del p.F371del | In Frame Del (DEL) | VAF 12/57 reads (21%) | catalogued as rs764352777; called by pindel, varscan2
- TRIM42 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV53882667, COSV53884864, COSV99648617; called by muse, mutect2, varscan2
- TRMT13 | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV100924031; called by muse, mutect2, varscan2
- TRMT61B | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100066715; called by muse, mutect2, varscan2
- TRPC5 | c.2863G>A p.D955N | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as COSV99462006; called by muse, mutect2, varscan2
- TTC3 | c.1634C>G p.S545C | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100695789; called by muse, mutect2, varscan2
- TTN | c.28312A>C p.K9438Q (on ENST00000591111; = p.K8511Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/155 reads (10%) | PolyPhen probably damaging (0.961); catalogued as COSV100621796; called by muse, mutect2, varscan2
- UBN2 | c.3940G>T p.A1314S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.03); catalogued as COSV99944242; called by muse, mutect2, varscan2
- UBXN6 | c.559C>A p.L187M | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as COSV100011351; called by muse, mutect2, varscan2
- UGT1A3 | c.219C>A p.N73K | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs200579886; called by muse, varscan2
- UNC45B | c.1649A>C p.Q550P | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as COSV99268959; called by muse, mutect2
- UNC5D | c.2531C>T p.A844V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99777347; called by muse, mutect2, varscan2
- UNC93A | c.269G>T p.W90L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1259874772, COSV100023495; called by muse, mutect2, varscan2
- VPS13D | c.9363G>C p.K3121N | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as COSV99167690; called by muse, mutect2, varscan2
- VPS4A | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1246570108, COSV99652055; called by muse, mutect2, varscan2
- VRK2 | c.1089dup p.V364Sfs*4 | Frame Shift Ins (INS) | VAF 14/48 reads (29%) | catalogued as rs768472226; called by mutect2, varscan2
- YTHDF1 | c.1662G>C p.Q554H | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV100945598; called by muse, mutect2, varscan2
- ZAN | c.6076G>A p.V2026I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.094); catalogued as COSV100769977; called by muse, mutect2, varscan2
- ZC3H7B | c.947T>G p.L316R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV100687554; called by muse, mutect2, varscan2
- ZDHHC14 | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100399358; called by muse, mutect2, varscan2
- ZFAND3 | c.214T>A p.S72T | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.55); PolyPhen benign (0.22); catalogued as COSV99765454; called by muse, mutect2, varscan2
- ZIK1 | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.084); catalogued as COSV100277573; called by muse, mutect2, varscan2
- ZKSCAN3 | c.276G>T p.E92D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99357049; called by muse, mutect2, varscan2
- ZNF385B | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200150920, COSV61176803; called by muse, mutect2, varscan2
- ZNF514 | c.1187G>C p.G396A | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV54635481, COSV99727866; called by muse, mutect2, varscan2
- ZNF606 | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100071904, COSV58704958; called by muse, mutect2, varscan2
- ZNF646 | c.3324G>C p.E1108D | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.836); catalogued as COSV99762510; called by muse, mutect2, varscan2
- ZNF668 | c.1181G>A p.C394Y | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100336778; called by muse, mutect2, varscan2
- ZNF699 | c.1406A>C p.H469P | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100427026; called by muse, mutect2, varscan2
- ZNF80 | c.791G>C p.S264T | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV100352089; called by muse, mutect2, varscan2
- ZNFX1 | c.3312+2T>G p.X1104_splice | Splice Site (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100870959; called by muse, mutect2, varscan2
- ZSCAN21 | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.438); catalogued as COSV99461159; called by muse, mutect2, varscan2
- ZSCAN29 | c.394A>C p.S132R | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.193); catalogued as rs151307138; called by muse, mutect2, varscan2
- ZSWIM8 | c.3750C>G p.I1250M (on ENST00000605216 / NM_001242487.2; = p.I1255M on NM_015037.3) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); catalogued as COSV100014183; called by muse, mutect2, varscan2
- APOA5 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.172); called by mutect2, varscan2
- CHRNA7 | c.1269_1284del p.Q425Tfs*58 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel
- CNTNAP4 | c.2690_2698del p.P897_T899del | In Frame Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- CXCL16 | c.113_115del p.C38del | In Frame Del (DEL) | VAF 12/40 reads (30%) | called by pindel, varscan2
- DNAJC22 | c.546_564del p.Y183Tfs*31 | Frame Shift Del (DEL) | VAF 20/43 reads (47%) | called by mutect2, pindel, varscan2
- DNAJC6 | c.2084_2091del p.T695Nfs*39 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- DPF1 | c.800_802del p.T267_G268delinsR | In Frame Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- FLT4 | c.3262_3268del p.D1088Cfs*39 | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | called by mutect2, pindel, varscan2
- HMGA2 | c.299_300del p.T100Ifs*116 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- IPO5 | c.1365_1368del p.Q456Vfs*30 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- LRP1B | c.10158_10174+16del p.X3386_splice | Splice Site (DEL) | VAF 9/75 reads (12%) | called by mutect2, pindel
- MED23 | c.3865_3869del p.N1289Hfs*6 | Frame Shift Del (DEL) | VAF 16/30 reads (53%) | called by mutect2, pindel, varscan2
- MINK1 | c.943del p.E315Rfs*29 | Frame Shift Del (DEL) | VAF 7/13 reads (54%) | called by mutect2, varscan2
- MYOM1 | c.874_876del p.E292del | In Frame Del (DEL) | VAF 22/92 reads (24%) | called by mutect2, pindel, varscan2
- NAP1L2 | c.827_840del p.L276Rfs*15 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- NFX1 | c.3176_3181del p.T1059_A1060del | In Frame Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- OR5P3 | c.418_431delinsCATGC p.V140_L144delinsHA | In Frame Del (DEL) | VAF 9/44 reads (20%) | called by pindel, varscan2*
- OR8U1 | c.905A>C p.K302T | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.272); called by muse, mutect2
- PEX19 | c.613_614del p.H206Sfs*10 | Frame Shift Del (DEL) | VAF 87/252 reads (35%) | called by pindel, varscan2
- PHF3 | c.4638del p.S1547Pfs*9 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.262C>A p.L88M | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- PRAMEF20 | c.1029_1031del p.L344del | In Frame Del (DEL) | VAF 97/560 reads (17%) | called by mutect2, pindel, varscan2
- SDK1 | c.1515_1516delinsT p.A506Lfs*57 | Frame Shift Del (DEL) | VAF 22/97 reads (23%) | called by pindel, varscan2*
- SLC38A10 | c.2833_2840del p.A945Sfs*19 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | called by mutect2, pindel, varscan2
- SRPRA | c.303_304del p.S102Cfs*10 | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | called by mutect2, pindel, varscan2
- TGFB1I1 | c.376_378del p.K126del (on ENST00000394863 / NM_001042454.3; = p.K109del on NM_015927.4) | In Frame Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel, varscan2
- TNFRSF8 | c.400_412del p.G134Sfs*57 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- AAK1 | c.693C>G p.V231= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV101276012, COSV68643081; called by muse, mutect2, varscan2
- ALK | c.513C>T p.S171= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs534035801, COSV101202431; ClinVar: likely benign; called by muse, mutect2, varscan2
- APOA2 | c.216G>A p.L72= | Silent (SNP) | VAF 96/208 reads (46%) | catalogued as rs768425737, COSV99248368; called by muse, mutect2, varscan2
- ATP10A | c.4062T>C p.S1354= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs1421036038, COSV100791009, COSV63517382; called by muse, mutect2, varscan2
- BBS12 | c.150C>T p.I50= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs1047061069, COSV100045033; called by muse, mutect2, varscan2
- CAMTA1 | c.2898C>T p.D966= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100351606; called by mutect2, varscan2
- CHRNA4 | c.621C>T p.G207= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as rs149407396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRND | c.1317G>T p.V439= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV51326932, COSV99286018; called by muse, mutect2
- DGAT1 | c.624C>G p.L208= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100184115; called by muse, mutect2, varscan2
- DSCAM | c.4449G>C p.L1483= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs764398319, COSV101260972; called by muse, mutect2, varscan2
- EMILIN2 | c.1959G>A p.V653= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV99598735; called by muse, mutect2, varscan2
- EPS8 | c.192A>G p.Q64= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV99843449; called by muse, mutect2, varscan2
- FAT3 | c.8268C>T p.F2756= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs773384938, COSV99968215; called by muse, mutect2, varscan2
- GPR12 | c.609G>A p.S203= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs1320204797, COSV101198002; called by muse, mutect2, varscan2
- GUF1 | c.1327T>C p.L443= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs1425721277, COSV99877396; called by muse, mutect2, varscan2
- H2BU1 | c.372C>T p.S124= | Silent (SNP) | VAF 22/106 reads (21%) | catalogued as COSV100797302; called by muse, mutect2, varscan2
- HBS1L | c.936C>T p.V312= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as COSV100892639; called by muse, mutect2, varscan2
- HCFC1 | c.708T>C p.D236= | Silent (SNP) | VAF 38/64 reads (59%) | catalogued as COSV100129529; called by muse, mutect2, varscan2
- HYDIN | c.11019C>A p.V3673= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV101157814; called by muse, mutect2
- IL10RA | c.1050C>T p.N350= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs772945751, COSV99923178; called by muse, mutect2, varscan2
- IRAG2 | c.4167C>T p.I1389= (on ENST00000636465; = p.I434= on NM_006152.4 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV100209571; called by muse, mutect2, varscan2
- KBTBD3 | c.1047T>C p.G349= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs145327190; called by muse, mutect2, varscan2
- KCNAB1 | c.201G>A p.E67= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV101051357, COSV67490954; called by muse, mutect2, varscan2
- KIF1B | c.3813G>C p.V1271= (on ENST00000377086 / NM_001365952.1; = p.V1225= on NM_015074.3) | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV99823206, COSV99823809; called by muse, mutect2, varscan2
- LIN54 | c.2025A>T p.P675= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as rs147498582; called by muse, mutect2, varscan2
- LRAT | c.138C>T p.H46= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100312149, COSV60476769; called by muse, mutect2, varscan2
- LRP12 | c.1263C>A p.S421= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV99408081; called by muse, mutect2, varscan2
- LRRC19 | c.972A>G p.P324= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV101195813; called by muse, mutect2, varscan2
- MARK4 | c.384G>A p.E128= | Silent (SNP) | VAF 32/104 reads (31%) | catalogued as COSV99488564; called by muse, mutect2, varscan2
- MYO6 | c.3099G>T p.A1033= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs374917329, COSV100889388; called by muse, mutect2, varscan2
- NID1 | c.1419C>T p.I473= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV99937902; called by muse, mutect2, varscan2
- NIM1K | c.1041C>T p.T347= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs778387825, COSV58144293; called by muse, mutect2, varscan2
- NPAP1 | c.462A>G p.Q154= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs761113460, COSV100275746, COSV61507229; called by muse, mutect2, varscan2
- OPHN1 | c.141C>T p.I47= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100830658; called by muse, mutect2, varscan2
- OR52B2 | c.681G>T p.V227= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV101603959; called by muse, mutect2, varscan2
- PARP4 | c.922C>T p.L308= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV101131857; called by muse, mutect2, varscan2
- PARPBP | c.1629A>G p.S543= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV100268291; called by muse, mutect2, varscan2
- PGM2L1 | c.1851G>C p.L617= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99995060; called by muse, mutect2, varscan2
- PGPEP1 | c.525G>A p.P175= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs147373225; called by muse, mutect2, varscan2
- PHF23 | c.183C>T p.G61= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs371010879; called by muse, mutect2
- POU4F1 | c.1092G>A p.A364= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs200593845, COSV65884294; called by muse, mutect2, varscan2
- PPEF2 | c.651A>T p.V217= | Silent (SNP) | VAF 60/206 reads (29%) | catalogued as COSV99714764; called by muse, mutect2, varscan2
- PTPRT | c.3732C>T p.A1244= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs754824702, COSV100629058, COSV61965855; called by muse, mutect2, varscan2
- RABGAP1L | c.54T>G p.A18= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV52333604, COSV99272390; called by muse, mutect2, varscan2
- RFPL2 | c.1125G>T p.G375= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as COSV99964420; called by muse, mutect2, varscan2
- RHBG | c.1071C>A p.V357= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as COSV99659848; called by muse, mutect2, varscan2
- SATB2 | c.243C>T p.H81= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs372121244; called by muse, mutect2, varscan2
- SKIV2L | c.822C>T p.A274= | Silent (SNP) | VAF 48/67 reads (72%) | catalogued as COSV100952818, COSV64812449; called by muse, mutect2, varscan2
- SLC12A8 | c.1398C>A p.L466= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100102813; called by muse, mutect2, varscan2
- SLC26A4 | c.771G>T p.L257= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99707291; called by muse, mutect2, varscan2
- SLC2A7 | c.447C>T p.Y149= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV101280819; called by muse, mutect2
- SLC7A11 | c.486A>G p.E162= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99763332; called by muse, mutect2, varscan2
- SPOP | c.861C>T p.V287= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100753489; called by muse, mutect2, varscan2
- STPG1 | c.387G>A p.S129= (on ENST00000337248 / NM_001199013.2; = p.S82= on NM_178122.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs11538188, COSV99134275; called by muse, mutect2, varscan2
- TAF1A | c.180T>C p.F60= | Silent (SNP) | VAF 40/156 reads (26%) | catalogued as COSV100601039; called by muse, varscan2
- TAS2R60 | c.924G>A p.K308= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV100223618; called by muse, mutect2, varscan2
- TGFBRAP1 | c.1104A>G p.E368= | Silent (SNP) | VAF 50/196 reads (26%) | catalogued as COSV51509734; called by muse, mutect2
- TMPRSS15 | c.2304C>T p.N768= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV99518588; called by muse, mutect2, varscan2
- TNFSF11 | c.537C>T p.S179= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV99520614; called by muse, mutect2, varscan2
- VAC14 | c.1224C>T p.L408= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs754648229, COSV99934030, COSV99934868; called by muse, mutect2, varscan2
- WDR24 | c.282C>A p.I94= (on ENST00000248142; = p.I32= on NM_032259.4) | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1356345044, COSV99556269, COSV99556763; called by muse, mutect2, varscan2
- ZBTB40 | c.2781C>G p.G927= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV100989069; called by muse, mutect2, varscan2
- ZFHX4 | c.9220C>T p.L3074= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV50841069; called by muse, mutect2, varscan2
- ZFP28 | c.1752T>C p.S584= | Silent (SNP) | VAF 39/130 reads (30%) | catalogued as rs994782723, COSV100019727; called by muse, mutect2, varscan2
- ZFP82 | c.1179T>G p.P393= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as COSV101089218; called by muse, mutect2, varscan2
- ZNF521 | c.531T>C p.S177= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as COSV100832855; called by muse, mutect2, varscan2
- ZSCAN2 | c.561C>G p.L187= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV100306934; called by muse, mutect2, varscan2
- ZSWIM1 | c.441G>T p.V147= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV99666764; called by muse, mutect2, varscan2
- AGAP7P | n.1004A>T | RNA (SNP) | VAF 35/149 reads (23%) | called by muse, mutect2, varscan2
- GBA3 | c.59-8255T>A | Intron (SNP) | VAF 48/208 reads (23%) | catalogued as rs1374182041; called by muse, mutect2, varscan2
- HERC2P3 | n.162A>T | RNA (SNP) | VAF 16/125 reads (13%) | called by mutect2, varscan2
- MCM7 | c.1848+104C>T | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as rs753879995, COSV100385062; called by muse, mutect2, varscan2
- MIR587 | n.52T>C | RNA (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- PCYT1B | c.*203T>A | 3'UTR (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100770764; called by muse, mutect2, varscan2
- SH2B2 | chr7:102283082 T>G | 5'Flank (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99476364; called by muse, mutect2, varscan2
- TMC5 | c.1049-3227C>A | Intron (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99572711; called by muse, mutect2, varscan2
- TTN | c.10360+1907G>C | Intron (SNP) | VAF 20/57 reads (35%) | catalogued as COSV100621797; called by muse, mutect2, varscan2
- XIST | n.9427A>T | RNA (SNP) | VAF 30/51 reads (59%) | called by muse, mutect2, varscan2
